Somatic mutation profile of tumor specimen C3L-07637-01 (aliquot CPT0484360007) from CPTAC case C3L-07637, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.9 years (23,702 days).
Specimen C3L-07637-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f79a4a6-d94e-44bb-b6d2-3602506ef7cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07637-32 (Blood Derived Normal), aliquot CPT0484510004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c859d8f6-6979-440c-9222-c68893bf2620

The open-access MAF lists 2,572 somatic variants for this specimen: 1,875 protein-altering or splice-affecting, 622 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,453, Silent 622, Frame Shift Del 226, Frame Shift Ins 78, Nonsense Mutation 64, Intron 38, In Frame Del 22, Splice Region 14, Splice Site 11, 5'Flank 11, 3'Flank 9, 3'UTR 9.

Variants (750 of 2,572; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 32/184 reads (17%) | catalogued as rs137852991, CM003583, COSV55395411; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.094); catalogued as rs587777384, CM1314068, CM143758, COSV61827671; ClinVar: pathogenic; called by muse, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 36/209 reads (17%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.582del p.F194Lfs*11 | Frame Shift Del (DEL) | VAF 22/180 reads (12%) | catalogued as rs367543026; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- C1QBP | c.562_564del p.Y188del | In Frame Del (DEL) | VAF 19/151 reads (13%) | catalogued as rs755568057; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDH1 | c.377del p.P126Rfs*89 | Frame Shift Del (DEL) | VAF 25/175 reads (14%) | catalogued as rs1060501215; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DHCR24 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs387906938, CM116727, COSV64874240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 32/173 reads (18%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- GANAB | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 58/367 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1565093675, COSV60461626; ClinVar: likely pathogenic; called by muse, varscan2
- GPI | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs137853583, CM930354, COSV62893986; ClinVar: pathogenic; called by muse, mutect2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 43/266 reads (16%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MTTP | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372321643, CM148264; ClinVar: likely pathogenic; called by muse, mutect2
- PANK2 | c.1257del p.F419Lfs*31 (on ENST00000316562 / NM_153638.3; = p.F128Lfs*31 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/165 reads (15%) | catalogued as rs1568574931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3141T>A p.H1047Q | Missense Mutation (SNP) | VAF 24/252 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55875891, COSV55920782; called by muse, mutect2
- PKHD1 | c.10452dup p.L3485Sfs*18 | Frame Shift Ins (INS) | VAF 37/215 reads (17%) | catalogued as rs771623148; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- POGZ | c.3847C>T p.Q1283* | Nonsense Mutation (SNP) | VAF 49/282 reads (17%) | catalogued as rs869312834, CM162600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.9305T>A p.L3102* | Nonsense Mutation (SNP) | VAF 12/241 reads (5%) | catalogued as rs886041949, COSV66537749; ClinVar: pathogenic; called by muse, mutect2
- SMAD3 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1060500766, CM158378, COSV59284912, COSV59287883; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- SMAD3 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1555414503, COSV59283463, COSV59289576, COSV59290127; ClinVar: likely pathogenic; called by muse, mutect2
- SMARCA2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs281875186, CM122553, COSV61805232, COSV61807107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.3075dup p.E1026Rfs*4 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.97600C>T p.R32534* (on ENST00000591111; = p.R25110* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 129/299 reads (43%) | catalogued as rs752697861, CM141094, COSV59993751; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 55/350 reads (16%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABAT | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761782312, COSV51628589; ClinVar: uncertain significance; called by muse, varscan2
- ABCA12 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs768133744, COSV55981680, COSV99789541; called by muse, mutect2, varscan2
- ABCA13 | c.6521del p.N2174Ifs*17 | Frame Shift Del (DEL) | VAF 17/159 reads (11%) | catalogued as rs908384447; called by mutect2, pindel
- ABCA2 | c.1055C>T p.A352V (on ENST00000614293; = p.A322V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/531 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as rs369679122; called by muse, mutect2, varscan2
- ABCB4 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs866847413, COSV55939007; called by muse, mutect2
- ABHD14A-ACY1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated, low confidence (0.22); catalogued as rs775701718; called by muse, mutect2, varscan2
- ABLIM2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773380850; called by muse, mutect2, varscan2
- AC004593.2 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs774356951, COSV56099686; called by muse, varscan2
- AC006059.2 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs756534911; called by muse, mutect2, varscan2
- ACAD10 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs887353946; called by muse, mutect2
- ACMSD | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs148826882; called by muse, mutect2, varscan2
- ACOD1 | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1166389307; called by muse, mutect2, varscan2
- ACTL8 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as rs148875551; called by muse, mutect2, varscan2
- ACVR2A | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | catalogued as COSV54018935; called by muse, mutect2
- ADAD2 | c.1513C>T p.R505C (on ENST00000315906 / NM_001145400.2; = p.R587C on NM_139174.4) | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as rs753285208, COSV51892397; called by muse, mutect2, varscan2
- ADAMTS15 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318520551; called by muse, mutect2
- ADAMTS2 | c.3521T>C p.V1174A | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV52366541; called by muse, mutect2, varscan2
- ADAMTS5 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53185094; called by muse, mutect2, varscan2
- ADAT3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as rs760364157; called by muse, mutect2
- ADGRA1 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs776299340; called by muse, mutect2, varscan2
- ADGRA2 | c.1574C>G p.A525G | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs774475444, COSV100177726; called by muse, mutect2
- ADGRA2 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs755614655, COSV55102829; called by muse, mutect2, varscan2
- ADGRB1 | c.4311del p.S1438Afs*30 | Frame Shift Del (DEL) | VAF 32/198 reads (16%) | catalogued as rs1221763121; called by mutect2, pindel, varscan2
- ADRA2A | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1410379168; called by muse, mutect2
- AFG3L2 | c.245dup p.N82Kfs*6 | Frame Shift Ins (INS) | VAF 13/103 reads (13%) | catalogued as rs775255820; called by mutect2, pindel, varscan2
- AGRN | c.4271C>T p.A1424V | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs777530290; called by muse, mutect2, varscan2
- AHDC1 | c.4750G>A p.G1584S | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); catalogued as rs774871172; called by muse, mutect2, varscan2
- AHDC1 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.356); catalogued as rs766911404; called by muse, mutect2
- AJAP1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs148805869; called by muse, varscan2
- AKIP1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1413331170; called by muse, mutect2, varscan2
- AKIP1 | c.425dup p.T143Dfs*23 | Frame Shift Ins (INS) | VAF 26/230 reads (11%) | catalogued as rs1308431992; called by pindel, varscan2
- ALDH6A1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs374613552; called by muse, mutect2, varscan2
- AMER2 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 142/394 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs750042960, COSV63435868; called by muse, varscan2
- AMH | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV55556224; called by muse, varscan2
- ANAPC2 | c.2130del p.G711Afs*52 | Frame Shift Del (DEL) | VAF 81/327 reads (25%) | catalogued as COSV60568599; called by mutect2, pindel, varscan2
- ANGEL1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374258511; called by muse, mutect2, varscan2
- ANK3 | c.3671del p.P1224Rfs*43 (on ENST00000280772 / NM_001320874.2; = p.P358Rfs*43 on NM_001149.3) | Frame Shift Del (DEL) | VAF 39/271 reads (14%) | catalogued as COSV99778899; called by mutect2, pindel, varscan2
- ANKRD11 | c.4349C>A p.S1450Y | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV99970166; called by muse, mutect2
- ANKRD12 | c.4577del p.N1526Mfs*10 | Frame Shift Del (DEL) | VAF 35/173 reads (20%) | catalogued as rs768306357; called by mutect2, pindel, varscan2
- ANKRD27 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs746397621, COSV60131342, COSV60131463; called by muse, mutect2, varscan2
- ANKRD40 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV53333065; called by muse, mutect2, varscan2
- ANKRD9 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1430260554; called by muse, mutect2, varscan2
- ANPEP | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200752447, COSV104410811; called by muse, varscan2
- ANXA11 | c.108del p.I37Sfs*114 | Frame Shift Del (DEL) | VAF 33/239 reads (14%) | catalogued as rs751349522; called by mutect2, pindel, varscan2
- AP3B2 | c.1154C>T p.T385I | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55608137; called by muse, mutect2, varscan2
- APLNR | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs374221224, COSV99951271; called by muse, mutect2
- APOB | c.5690G>A p.R1897H | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs199510126, CM141896, COSV51922311, COSV51953906; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- APOBEC3G | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs756302637, COSV68470165; called by muse, mutect2, varscan2
- APOLD1 | c.820C>T p.R274C (on ENST00000326765 / NM_001130415.2; = p.R243C on NM_030817.3) | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.093); catalogued as rs1487455396; called by muse, mutect2, varscan2
- AQP8 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs748173198, COSV54844910; called by muse, mutect2
- ARHGAP15 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 41/348 reads (12%) | catalogued as rs754914086, COSV54511752; called by muse, varscan2
- ARHGAP23 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1290381552; called by muse, mutect2
- ARHGEF40 | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs762564238, COSV53881515; called by muse, mutect2
- ARID3C | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 133/446 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52409278; called by muse, mutect2, varscan2
- ARMC3 | c.833del p.K278Sfs*45 | Frame Shift Del (DEL) | VAF 26/200 reads (13%) | catalogued as COSV53065399; called by mutect2, pindel, varscan2
- ASB13 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs60413325, COSV63091009, COSV99069891; called by muse, mutect2
- ASH1L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs374072309; called by muse, mutect2, varscan2
- ASIC3 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as rs750604015; called by muse, mutect2
- ASL | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs1483827918; called by muse, mutect2, varscan2
- ASPM | c.4444C>T p.R1482W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs371997190; called by muse, mutect2
- ASZ1 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs186384831; called by muse, mutect2, varscan2
- ASZ1 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52913203; called by muse, mutect2
- ATAT1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs771581919; called by muse, mutect2, varscan2
- ATG2A | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781153736; called by muse, mutect2, varscan2
- ATG2A | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778745921; called by muse, mutect2
- ATIC | c.1504-1G>T p.X502_splice | Splice Site (SNP) | VAF 46/169 reads (27%) | catalogued as rs1051506093; called by muse, mutect2, varscan2
- ATOH1 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1159691711; called by muse, mutect2
- ATP12A | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54513125; called by muse, mutect2
- ATP1A4 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs773940781, COSV63625715; called by muse, mutect2, varscan2
- ATP2A1 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); catalogued as rs866421756, COSV100707138; called by muse, mutect2, varscan2
- ATP2B2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59492447, COSV59503549; called by muse, mutect2, varscan2
- ATP8B1 | c.3220G>A p.V1074I | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.906); catalogued as rs754583409; called by muse, mutect2, varscan2
- AXIN1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1168676445; called by muse, mutect2
- AXIN2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100196600; called by muse, mutect2
- B3GNT6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62828372; called by muse, varscan2
- B4GALT6 | c.1088G>T p.R363M | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs1156671433, COSV99380258; called by muse, mutect2
- BARX2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV55651632; called by muse, mutect2, varscan2
- BAZ2A | c.5378G>A p.R1793Q | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs762971471; called by muse, mutect2, varscan2
- BCAM | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs373734560, COSV54301642; called by muse, mutect2, varscan2
- BCL9 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782102524; called by muse, mutect2, varscan2
- BCR | c.3380C>T p.T1127M | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs35812689; called by muse, mutect2
- BEAN1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs551847092; called by muse, mutect2, varscan2
- BFSP2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749419128, COSV56588172; called by muse, mutect2
- BIRC6 | c.2326C>A p.L776I | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV70206014; called by muse, mutect2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 21/207 reads (10%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BOD1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs747435012, COSV99603561; called by muse, mutect2, varscan2
- BPIFB4 | c.1813G>A p.V605M | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs138732736; called by muse, mutect2
- BRD1 | c.3098G>A p.R1033Q (on ENST00000216267 / NM_001349940.1; = p.R1164Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs201232527, COSV53454443; called by muse, mutect2, varscan2
- BRD4 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1454979767, COSV54584641; called by muse, mutect2, varscan2
- BRINP2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as rs751983601, COSV64176567; called by muse, mutect2, varscan2
- BSN | c.7585C>T p.R2529W | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs200351851, COSV56524195; called by muse, varscan2
- BSN | c.7817G>A p.R2606Q | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1056155060, COSV56519234; called by muse, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, varscan2
- BTNL9 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV59794659, COSV59799644; called by muse, mutect2, varscan2
- BZW1 | c.401del p.K134Sfs*6 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs1559311293; called by mutect2, pindel, varscan2
- C10orf90 | c.395del p.G132Afs*76 | Frame Shift Del (DEL) | VAF 41/272 reads (15%) | catalogued as rs756932045; called by mutect2, pindel, varscan2
- C16orf72 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59916415; called by muse, mutect2, varscan2
- C19orf47 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs113030113; called by muse, mutect2, varscan2
- C6orf132 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 37/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362743264; called by muse, mutect2, varscan2
- CA5B | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181134647, COSV100590847, COSV59415674; called by muse, mutect2, varscan2
- CABP7 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53363076; called by muse, mutect2, varscan2
- CACNA1A | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs184473835; called by muse, mutect2
- CACNA1C | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768830617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.1640dup p.G548Wfs*31 | Frame Shift Ins (INS) | VAF 42/292 reads (14%) | catalogued as rs767555827; called by mutect2, varscan2
- CACNA1I | c.3176T>C p.L1059P | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs949844214; called by mutect2, varscan2
- CACNA1I | c.6242G>A p.R2081Q | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs1016234471; called by muse, mutect2, varscan2
- CACNB2 | c.988C>T p.R330C (on ENST00000324631 / NM_201596.3; = p.R275C on NM_000724.4) | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326422016; called by muse, mutect2, varscan2
- CACNB2 | c.1880G>A p.R627H (on ENST00000324631 / NM_201596.3; = p.R572H on NM_000724.4) | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as rs758934103, COSV56627222; called by muse, mutect2, varscan2
- CACNG8 | c.1084del p.A362Rfs*98 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs1196747223; called by mutect2, pindel, varscan2
- CACTIN | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750803352; called by muse, mutect2, varscan2
- CAMK4 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56671919; called by muse, mutect2
- CAMKK2 | c.1642dup p.R548Pfs*66 | Frame Shift Ins (INS) | VAF 24/252 reads (10%) | catalogued as rs774981105; called by mutect2, pindel
- CAMTA2 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.207); catalogued as rs890876233, COSV100772365, COSV61837868; called by muse, mutect2
- CAPN15 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs144469520; called by muse, mutect2, varscan2
- CAPN9 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs373142698, COSV55238485; called by muse, mutect2, varscan2
- CAPZA2 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as rs1269192002, COSV63266391; called by muse, mutect2
- CARD14 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs143600438; ClinVar: uncertain significance; called by muse, varscan2
- CARMIL3 | c.3751_3753del p.K1251del | In Frame Del (DEL) | VAF 31/212 reads (15%) | catalogued as rs779248351; called by pindel, varscan2
- CARS2 | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1400382871; called by muse, mutect2
- CAVIN4 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs879044419; called by muse, mutect2, varscan2
- CBR3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 64/372 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs979603464; called by muse, mutect2, varscan2
- CCDC179 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as rs780995888; called by muse, mutect2, varscan2
- CCDC39 | c.2813del p.K938Rfs*11 | Frame Shift Del (DEL) | VAF 29/139 reads (21%) | catalogued as rs1206111457; called by mutect2, pindel, varscan2
- CCDC70 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54430525, COSV99665370; called by muse, mutect2
- CCDC71 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs373036352; called by muse, mutect2, varscan2
- CCL24 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1160493859; called by muse, mutect2
- CCN2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63466945; called by muse, mutect2, varscan2
- CCT2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781508198, COSV54742002; called by muse, mutect2, varscan2
- CD200 | c.745G>A p.D249N (on ENST00000473539 / NM_001004196.3; = p.D224N on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs759192172, COSV59862072; called by muse, mutect2, varscan2
- CDC25B | c.712A>G p.S238G (on ENST00000245960 / NM_021873.3; = p.S224G on NM_004358.4) | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs111545759; called by muse, mutect2, varscan2
- CDC42BPG | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 73/406 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.906); catalogued as rs543818334, COSV61347016; called by muse, mutect2, varscan2
- CDC73 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 12/182 reads (7%) | catalogued as CM045278, COSV66467849; called by muse, mutect2
- CDK20 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as rs374349865; called by muse, varscan2
- CDKL5 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1241585738; called by muse, mutect2, varscan2
- CDR2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as rs1216529932; called by muse, mutect2
- CECR2 | c.2677del p.V893Cfs*7 (on ENST00000342247 / NM_001290047.2; = p.V710Cfs*7 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 29/198 reads (15%) | catalogued as COSV52843015; called by mutect2, pindel, varscan2
- CEMIP | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913148462; called by muse, mutect2, varscan2
- CENPP | c.519dup p.V174Cfs*5 | Frame Shift Ins (INS) | VAF 38/178 reads (21%) | catalogued as rs750494120; called by mutect2, varscan2
- CENPW | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); catalogued as rs745347945, COSV64176920; called by muse, mutect2, varscan2
- CEP152 | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs184240876, COSV57858650; called by muse, mutect2, varscan2
- CEP41 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as COSV56218560; called by muse, mutect2
- CES4A | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs775459183, COSV58653069; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 55/164 reads (34%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP44 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55613499; called by muse, mutect2, varscan2
- CHD2 | c.3018G>T p.E1006D | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV101245226; called by muse, mutect2
- CHRNA4 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as rs890168894, COSV64720807; called by muse, mutect2
- CIC | c.4574C>T p.T1525M | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs958200675, COSV99358684; called by muse, mutect2, varscan2
- CIITA | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1430455427, COSV60856890; called by muse, mutect2, varscan2
- CLCNKB | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs140923370; called by muse, mutect2, varscan2
- CLTC | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV52249809; called by muse, mutect2
- CLUH | c.2851C>T p.R951C (on ENST00000435359; = p.R990C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs779000573; called by muse, mutect2, varscan2
- CNKSR3 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.009); catalogued as rs925966534, COSV70481099; called by muse, mutect2
- CNNM2 | c.274del p.A92Rfs*4 | Frame Shift Del (DEL) | VAF 46/289 reads (16%) | catalogued as rs768722573; called by mutect2, pindel, varscan2
- CNOT8 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226500708; called by muse, mutect2, varscan2
- CNR1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs538741714; called by muse, mutect2, varscan2
- CNTNAP5 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70487421; called by muse, mutect2, varscan2
- COL24A1 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1407358772; called by muse, mutect2, varscan2
- COL27A1 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 50/484 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs555858459, COSV61922742; called by muse, varscan2
- COL5A3 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757109962, COSV53410094; called by muse, varscan2
- COL6A5 | c.4770G>T p.Q1590H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV55218351; called by muse, varscan2
- COL7A1 | c.6329del p.P2110Lfs*96 | Frame Shift Del (DEL) | VAF 23/228 reads (10%) | catalogued as COSV100097622; called by mutect2, pindel
- CPSF1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs782015229; called by muse, mutect2, varscan2
- CPT1C | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774069280; called by muse, mutect2, varscan2
- CR1 | c.4987del p.L1663* | Frame Shift Del (DEL) | VAF 18/216 reads (8%) | catalogued as rs1355906430; called by mutect2, pindel
- CREB3L1 | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs536813830; called by muse, mutect2
- CREBZF | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.083); catalogued as rs754039997; called by muse, mutect2
- CRHR1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1030829316; called by muse, mutect2, varscan2
- CRMP1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs145169573; called by muse, mutect2, varscan2
- CROT | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.116); catalogued as rs916197132; called by muse, mutect2
- CRYGS | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs61743714; called by muse, mutect2, varscan2
- CSMD2 | c.4765G>A p.E1589K | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs749349455, COSV53914620; called by muse, mutect2, varscan2
- CSNK1D | c.1172A>G p.D391G | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as rs761681213; called by muse, mutect2, varscan2
- CSPG4 | c.2762A>G p.H921R | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1030545533, COSV57894514; called by muse, mutect2
- CSPG4 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756062229, COSV57890072; called by muse, mutect2, varscan2
- CTNND2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs1038105285, COSV100469533; called by muse, mutect2
- CYP2A13 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs368131195, COSV100386920; called by muse, mutect2
- CYP2C19 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs200150287, CM1510894; called by muse, mutect2
- D2HGDH | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs199908032, CM101390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DACT2 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs1158392417; called by muse, mutect2, varscan2
- DAP3 | c.217del p.Q73Rfs*16 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | catalogued as rs757230517; called by mutect2, pindel
- DCAF15 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs140182834; called by muse, varscan2
- DCBLD2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939159801, COSV100472866; called by muse, mutect2, varscan2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 36/263 reads (14%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DDX27 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 17/230 reads (7%) | catalogued as rs558152082, COSV65629064; called by muse, mutect2
- DENND1C | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.362); catalogued as rs757432826; called by muse, mutect2, varscan2
- DGKI | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 42/226 reads (19%) | catalogued as COSV55944007; called by mutect2, varscan2
- DGKK | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65708764; called by mutect2, varscan2
- DHX16 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 62/440 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1253072340, COSV64582659; called by muse, mutect2, varscan2
- DICER1 | c.3238G>A p.V1080M | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV58627368; called by muse, mutect2, varscan2
- DIPK1B | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1407806947; called by muse, mutect2
- DMBT1 | c.3523G>A p.A1175T (on ENST00000338354 / NM_001377530.1; = p.A676T on NM_004406.3) | Missense Mutation (SNP) | VAF 78/462 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV57559325; called by muse, mutect2, varscan2
- DMWD | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 57/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769696852; called by muse, mutect2, varscan2
- DNAH2 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66721994; called by muse, mutect2
- DNAH6 | c.7915G>A p.V2639M | Missense Mutation (SNP) | VAF 19/353 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1023880395, COSV52863519; called by muse, mutect2
- DNAH9 | c.5920C>T p.P1974S | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52351583; called by muse, mutect2
- DNAH9 | c.10340G>A p.R3447H | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769435149, COSV52361311; called by muse, mutect2, varscan2
- DNAJC1 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs773581393; called by muse, mutect2, varscan2
- DNAJC10 | c.1916C>A p.P639Q | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1255368694, COSV51135614, COSV51141750; called by muse, mutect2, varscan2
- DNER | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1203058743; called by muse, varscan2
- DNMT3B | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM016244, COSV52422122; called by muse, varscan2
- DNMT3B | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1267164985, COSV52416625, COSV52424854; called by muse, varscan2
- DOCK1 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as rs150790785; called by muse, mutect2
- DOCK6 | c.5581C>T p.R1861C | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs573654195; called by muse, mutect2, varscan2
- DOCK6 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772731799, COSV99624902; called by muse, mutect2, varscan2
- DOCK7 | c.5059C>T p.R1687* (on ENST00000635253 / NM_001367561.1; = p.R1656* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 34/248 reads (14%) | catalogued as COSV52001041; called by muse, varscan2
- DPP6 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1169776772; called by muse, varscan2
- DPP6 | c.2153G>A p.S718N (on ENST00000377770 / NM_001364500.2; = p.S656N on NM_001936.5) | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV100122401; called by muse, mutect2, varscan2
- DPP9 | c.1090G>A p.A364T (on ENST00000598800; = p.A393T on NM_139159.5) | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs774925863, COSV53594176; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DSE | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs369887455; called by muse, mutect2, varscan2
- DST | c.17872C>T p.R5958C (on ENST00000361203 / NM_001374722.1; = p.R3655C on NM_015548.5) | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348477527; called by muse, mutect2, varscan2
- DTX2 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 46/367 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs772447293; called by muse, mutect2, varscan2
- DTX4 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250004314; called by muse, mutect2, varscan2
- DUSP26 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as rs778152331; called by muse, mutect2, varscan2
- E2F5 | c.132del p.G46Afs*40 | Frame Shift Del (DEL) | VAF 14/136 reads (10%) | catalogued as rs1554681742; called by mutect2, pindel
- EDN3 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs376041123, COSV61110125; called by muse, mutect2
- EED | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.827); catalogued as COSV54553870; called by muse, mutect2, varscan2
- EEF1D | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 80/381 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1292991211, COSV52785551; called by muse, mutect2, varscan2
- EFCAB10 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 14/226 reads (6%) | catalogued as rs1269295014; called by muse, mutect2
- EFR3B | c.852G>A p.P284= | Splice Region (SNP) | VAF 66/261 reads (25%) | catalogued as rs1416443427; called by muse, mutect2, varscan2
- EGR3 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as rs760574595; called by muse, mutect2, varscan2
- EID3 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as rs765550437, COSV100723279; called by muse, mutect2, varscan2
- EIF4E1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs1296660855, COSV53781927; called by muse, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 20/155 reads (13%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELF4 | c.1021del p.Q341Rfs*30 | Frame Shift Del (DEL) | VAF 65/208 reads (31%) | catalogued as COSV57452819, COSV57454138; called by mutect2, varscan2
- ELFN1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as rs528523341; called by muse, mutect2
- ELMO3 | c.1910C>T p.P637L (on ENST00000652269; = p.P584L on NM_024712.5) | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs780276869; called by muse, mutect2, varscan2
- EME2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs377368785; called by muse, mutect2, varscan2
- EP400 | c.2465G>A p.G822E | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs1378976765; called by muse, mutect2
- EP400 | c.4069G>A p.A1357T | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs781782241, COSV57786122; called by muse, mutect2, varscan2
- EPHA1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs111641464, COSV51973380, COSV51975137; called by muse, mutect2, varscan2
- EPHA10 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764448343, COSV60403003, COSV60403387; called by muse, mutect2, varscan2
- EPHA3 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | catalogued as rs774448099, COSV60696980, COSV60729273; called by muse, mutect2, varscan2
- EPHB1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs747682274, COSV67653214; called by muse, mutect2, varscan2
- EPHB3 | c.2882C>T p.T961M | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs574118020; called by muse, mutect2, varscan2
- ERC1 | c.2467G>A p.D823N (on ENST00000360905 / NM_178040.4; = p.D795N on NM_178039.4) | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); catalogued as rs757804797; called by muse, mutect2, varscan2
- ERCC6 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs755377100; called by muse, mutect2, varscan2
- ERLEC1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407744428; called by muse, mutect2, varscan2
- ERMARD | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330438411; called by muse, mutect2
- ESS2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 47/436 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142803658; called by muse, varscan2
- EVC2 | c.3406G>A p.G1136R | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs567949398, COSV60395193; called by muse, mutect2
- EXPH5 | c.278dup p.N93Kfs*2 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | catalogued as rs1305598119; called by mutect2, pindel, varscan2
- FAAP100 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as rs1382505343; called by muse, mutect2
- FAM107A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs769432083, COSV62980943; called by muse, mutect2, varscan2
- FAM161A | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs1299770851; called by muse, mutect2
- FAM166B | c.652G>A p.A218T (on ENST00000399742 / NM_001164310.3; = p.C195Y on NM_001099951.4) | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1387515914; called by muse, mutect2
- FAM227B | c.749T>A p.I250K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV54819505; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs746983128; called by mutect2, varscan2
- FASN | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs569723911, COSV60760799; called by muse, mutect2, varscan2
- FAT3 | c.6253G>A p.V2085M | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449189758; called by muse, mutect2, varscan2
- FAT4 | c.10014G>C p.L3338F | Missense Mutation (SNP) | VAF 16/315 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV58678153; called by muse, mutect2
- FBN2 | c.1190del p.G397Afs*92 | Frame Shift Del (DEL) | VAF 31/246 reads (13%) | catalogued as COSV52504665, COSV52528362; called by mutect2, pindel, varscan2
- FBXO31 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs781136689, COSV61148490; called by muse, varscan2
- FBXW10 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs78640521; called by muse, mutect2, varscan2
- FCHSD2 | c.1941del p.K648Sfs*122 | Frame Shift Del (DEL) | VAF 32/199 reads (16%) | catalogued as rs1565281509; called by mutect2, pindel, varscan2
- FDX2 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 22/286 reads (8%) | catalogued as rs901710095; called by muse, mutect2
- FER1L6 | c.4340G>A p.R1447H | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766629020, COSV67547795; called by muse, mutect2, varscan2
- FEV | c.704del p.G235Afs*124 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | catalogued as rs141171754, COSV55387521; called by mutect2, pindel, varscan2
- FGFR4 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs763979974, COSV52810460; called by muse, mutect2, varscan2
- FHDC1 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1297175605; called by muse, varscan2
- FKBP6 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782250810; called by muse, mutect2, varscan2
- FKRP | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM051476, CM062722; called by muse, mutect2
- FKTN | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1343750016; called by muse, mutect2
- FLNB | c.4832C>T p.T1611M | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs547507630; called by muse, mutect2, varscan2
- FMNL1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as rs368818105; called by muse, mutect2, varscan2
- FN1 | c.6398T>C p.I2133T (on ENST00000359671 / NM_001365524.2; = p.I2102T on NM_002026.4) | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60547293; called by muse, mutect2, varscan2
- FNDC3A | c.1904G>A p.R635H (on ENST00000492622 / NM_001079673.2; = p.R579H on NM_014923.5) | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs367719937; called by muse, mutect2, varscan2
- FNIP1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs192426636; called by muse, mutect2, varscan2
- FNTB | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs376882084; called by muse, mutect2, varscan2
- FOXB2 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 43/584 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1357380848; called by muse, mutect2
- FOXD3 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1216862420; called by muse, mutect2
- FOXD3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs1463307763, COSV64380230; called by muse, mutect2, varscan2
- FOXK1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1490292353; called by muse, mutect2, varscan2
- FOXK1 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1457779399; called by muse, mutect2, varscan2
- FRG2B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1296108284, COSV101423533; called by muse, varscan2
- FRMPD4 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101043659; called by muse, mutect2, varscan2
- FSIP2 | c.2319dup p.C774Mfs*3 | Frame Shift Ins (INS) | VAF 18/176 reads (10%) | catalogued as rs1559025161; called by mutect2, pindel
- FZD9 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV100750827; called by muse, mutect2, varscan2
- GABPB1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV55014292; called by muse, mutect2, varscan2
- GABRA3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs139179813, COSV64799220; called by muse, mutect2, varscan2
- GABRA4 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51928039; called by muse, mutect2
- GABRB3 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347499222, COSV54661500, COSV54683742; called by muse, mutect2, varscan2
- GABRE | c.471dup p.R158* | Frame Shift Ins (INS) | VAF 25/160 reads (16%) | catalogued as rs1569454387; called by mutect2, pindel, varscan2
- GABRP | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1286518870; called by muse, mutect2
- GABRR1 | c.695del p.K232Rfs*6 | Frame Shift Del (DEL) | VAF 21/197 reads (11%) | catalogued as COSV65619657; called by mutect2, pindel
- GAPVD1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.588); catalogued as rs202094140; called by muse, mutect2, varscan2
- GAS6 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs769396670; called by muse, varscan2
- GATA5 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782198035, COSV53345213; called by muse, mutect2, varscan2
- GCGR | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs28522411, COSV68779834; called by muse, mutect2
- GGA2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1352861234, COSV59167693; called by muse, mutect2, varscan2
- GJC3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs755056506; called by muse, varscan2
- GLI3 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 60/376 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs201268608; called by muse, mutect2, varscan2
- GNB3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs143381578; called by muse, mutect2, varscan2
- GPR101 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs887953877, COSV53237364; called by muse, mutect2, varscan2
- GPR32 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs747829098, COSV54514925, COSV54515776; called by muse, mutect2
- GPR39 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs753477887; called by muse, mutect2, varscan2
- GPR6 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as rs1004146420, COSV51573272; called by muse, mutect2, varscan2
- GREB1 | c.4690G>A p.A1564T | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as rs1293685704, COSV52193285; called by muse, varscan2
- GRIA3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763033824, COSV99989783; called by muse, mutect2, varscan2
- GRID2IP | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs544688737; called by muse, mutect2, varscan2
- GRIK5 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 18/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555872809, COSV99490929; called by muse, mutect2
- GRIN2B | c.4078G>A p.G1360R | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.399); catalogued as COSV101663110; called by muse, mutect2, varscan2
- GRIN2C | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs766009350; called by muse, mutect2, varscan2
- GRK1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936018736, COSV59551630; called by muse, mutect2, varscan2
- GRM5 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as COSV59604139; called by muse, mutect2
- GSG1L2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1456511580; called by muse, mutect2, varscan2
- GTF2E1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs781010638, COSV52203570; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1384263020, COSV56090008; called by muse, mutect2
- H1-8 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs759139474; called by muse, mutect2, varscan2
- H2BC5 | c.299G>C p.R100P | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV56802402; called by muse, mutect2
- HACL1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756546304; called by muse, mutect2, varscan2
- HAUS6 | c.1588del p.S530Vfs*12 | Frame Shift Del (DEL) | VAF 45/166 reads (27%) | catalogued as rs34558496; called by mutect2, pindel, varscan2
- HCN4 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.238); catalogued as rs767160441; called by muse, varscan2
- HDAC10 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1236390633, COSV50548224; called by muse, varscan2
- HERC2 | c.6779T>C p.L2260P | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781582841; called by muse, mutect2
- HERC2 | c.2603C>T p.T868M | Missense Mutation (SNP) | VAF 15/389 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs771006588; called by muse, mutect2
- HEYL | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as rs1276609405; called by muse, mutect2
- HHIP | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 14/296 reads (5%) | catalogued as COSV56837492; called by muse, mutect2
- HLA-DRA | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1257068252; called by muse, mutect2, varscan2
- HOGA1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs140370320; called by muse, mutect2, varscan2
- HOMER2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757701596, COSV58485587; called by muse, mutect2, varscan2
- HOXA3 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs769208429, COSV57825475; called by muse, mutect2, varscan2
- HOXA3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 58/528 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as rs200842771; called by muse, mutect2, varscan2
- HOXA3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 74/565 reads (13%) | catalogued as rs1248247321, COSV100415711; called by muse, mutect2, varscan2
- HS3ST2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs929267981; called by muse, mutect2, varscan2
- HS3ST3A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754668033; called by muse, mutect2, varscan2
- HTR3D | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.018); catalogued as rs745457011, COSV61913233; called by muse, mutect2, varscan2
- HYDIN | c.10226G>A p.R3409H | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs780293022; called by muse, mutect2, varscan2
- IDH3A | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs762865075, COSV51904326; called by muse, mutect2
- IGLL1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 35/402 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs375103902; called by muse, mutect2
- IL10 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 39/233 reads (17%) | catalogued as rs766492258, COSV65594772, COSV65594856; called by muse, mutect2, varscan2
- IL11RA | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs775793536, COSV52404779; called by muse, mutect2, varscan2
- IL18BP | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52620258; called by muse, mutect2
- ILDR1 | c.321dup p.Q108Afs*3 | Frame Shift Ins (INS) | VAF 27/257 reads (11%) | catalogued as rs748351772; called by mutect2, pindel, varscan2
- INCENP | c.2105G>A p.R702Q (on ENST00000394818 / NM_001040694.2; = p.R698Q on NM_020238.3) | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs553981745; called by mutect2, varscan2
- INKA2 | c.559del p.A187Hfs*20 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | catalogued as rs751997684, COSV61878369; called by mutect2, pindel
- IPO5 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1252386767; called by muse, mutect2
- IRF5 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV50857513; called by muse, mutect2
- ITGA2B | c.2702C>G p.S901W | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as CM960885; called by muse, mutect2
- ITGA8 | c.466T>C p.W156R | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200530763; called by muse, mutect2, varscan2
- ITGA9 | c.2890-1G>T p.X964_splice | Splice Site (SNP) | VAF 13/214 reads (6%) | catalogued as COSV53244892; called by muse, mutect2
- ITGAE | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs373069448; called by muse, mutect2, varscan2
- ITGAM | c.3097T>C p.C1033R (on ENST00000648685 / NM_001145808.2; = p.C1032R on NM_000632.4) | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766743329; called by muse, mutect2, varscan2
- ITGB4 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs185794989, COSV52326540; called by muse, mutect2, varscan2
- ITPR2 | c.6863G>A p.R2288Q | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs773496161; called by muse, mutect2, varscan2
- JAG1 | c.3289C>T p.R1097W | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768554175, HM080117, COSV54761313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAKMIP1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs149854773; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- JDP2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs950796096; called by muse, mutect2, varscan2
- JPH1 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.413); catalogued as rs371404335; called by muse, mutect2, varscan2
- KANK1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs191266626; called by muse, mutect2, varscan2
- KATNAL2 | c.54C>T p.C18= | Splice Region (SNP) | VAF 29/161 reads (18%) | catalogued as rs945185126; called by muse, mutect2, varscan2
- KAZN | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV101054857; called by muse, mutect2, varscan2
- KCNC2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100128815; called by muse, mutect2
- KCNJ2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM125448, COSV99696455; called by muse, mutect2, varscan2
- KCNK17 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757619419; called by mutect2, varscan2
- KCNK3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs778446835; called by muse, mutect2, varscan2
- KCNMA1 | c.3296G>A p.R1099H (on ENST00000286628 / NM_001161352.2; = p.R1041H on NM_002247.4) | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs768399208, COSV54265081; called by muse, varscan2
- KCNQ2 | c.2331del p.E778Rfs*152 (on ENST00000359125 / NM_172107.4; = p.E750Rfs*152 on NM_004518.6) | Frame Shift Del (DEL) | VAF 37/328 reads (11%) | catalogued as COSV60545621; called by mutect2, varscan2
- KCNQ2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779076192; called by muse, mutect2
- KCNS3 | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV58405636; called by muse, mutect2
- KCNT1 | c.2138C>T p.S713L (on ENST00000488444; = p.S732L on NM_020822.3) | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs774281111; called by muse, mutect2, varscan2
- KDM5C | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1556849167, COSV64767504; called by muse, mutect2, varscan2
- KHSRP | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs780220491, COSV101231121; called by muse, mutect2, varscan2
- KIAA0586 | c.622C>T p.R208C (on ENST00000619416 / NM_001244190.2; = p.R223C on NM_014749.5) | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs573870218; called by muse, mutect2, varscan2
- KIAA0586 | c.3212C>T p.S1071L (on ENST00000619416 / NM_001244190.2; = p.S1010L on NM_014749.5) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs772256006, COSV54173926; called by muse, mutect2, varscan2
- KIF18B | c.1690del p.A564Hfs*29 (on ENST00000593135 / NM_001265577.2; = p.A576Hfs*29 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 32/236 reads (14%) | catalogued as rs779064855; called by mutect2, varscan2
- KIF21B | c.4895G>A p.R1632H (on ENST00000422435 / NM_001252100.2; = p.R1619H on NM_017596.4) | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs757337335, COSV59752797; called by muse, mutect2, varscan2
- KIF4A | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs746727117; called by muse, mutect2, varscan2
- KIFC1 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 71/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201789629; called by muse, mutect2, varscan2
- KLF11 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs868399686, COSV100007828; ClinVar: uncertain significance; called by muse, mutect2
- KLF16 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs900482397; called by muse, mutect2, varscan2
- KLHDC1 | c.89dup p.Y31Lfs*5 | Frame Shift Ins (INS) | VAF 26/187 reads (14%) | catalogued as rs769808390; called by mutect2, varscan2
- KLHL10 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.746); catalogued as rs918930712, COSV53173352; called by muse, mutect2, varscan2
- KLRG2 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 28/518 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV61800857; called by muse, mutect2
- KMT2D | c.15167T>C p.L5056P | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56415127; called by muse, mutect2, varscan2
- KMT2D | c.9728G>A p.S3243N | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99984303; called by muse, mutect2, varscan2
- KRT14 | c.77del p.G26Afs*92 | Frame Shift Del (DEL) | VAF 38/330 reads (12%) | catalogued as rs1450156695; called by mutect2, varscan2
- KRT33A | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs374293948; called by muse, mutect2
- KRT34 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 65/352 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.479); catalogued as rs369876817; called by muse, mutect2, varscan2
- KRT36 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV60204428; called by muse, mutect2
- LAMA2 | c.7051G>A p.V2351I | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs140680416; called by muse, mutect2, varscan2
- LAMA4 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs149430073; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 33/149 reads (22%) | catalogued as rs747409331; called by mutect2, varscan2
- LAMC3 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 43/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs766091947; called by muse, mutect2, varscan2
- LAMC3 | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1411067036; called by muse, mutect2, varscan2
- LATS2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1390242703; called by muse, mutect2
- LDHAL6A | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1456537887; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 24/205 reads (12%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel
- LHX8 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV99633912; called by muse, mutect2
- LIMA1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs756628778; called by muse, mutect2, varscan2
- LMTK2 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 32/475 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs756034075, COSV51997663; called by muse, mutect2
- LORICRIN | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 38/348 reads (11%) | PolyPhen benign (0.142); catalogued as rs746390232; called by muse, mutect2, varscan2
- LRAT | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776906234; called by muse, mutect2, varscan2
- LRP1 | c.11926G>A p.D3976N | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768055016; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 34/237 reads (14%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP1B | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs766749470, COSV67192207; called by muse, mutect2, varscan2
- LRRC14B | c.765del p.T256Pfs*36 | Frame Shift Del (DEL) | VAF 54/328 reads (16%) | catalogued as rs748566980; called by mutect2, varscan2
- LRRC18 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776174712, COSV53285438; called by muse, mutect2, varscan2
- LRRC8A | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52189666; called by muse, mutect2, varscan2
- LSS | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554557257; called by muse, varscan2
- LTF | c.183del p.I62Sfs*15 | Frame Shift Del (DEL) | VAF 26/165 reads (16%) | catalogued as COSV51610799; called by mutect2, pindel, varscan2
- LUC7L | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs775175063; called by muse, mutect2
- LY6D | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as rs780183494; called by muse, mutect2, varscan2
- LY9 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs202197584; called by muse, mutect2, varscan2
- MACF1 | c.9613A>G p.R3205G | Missense Mutation (SNP) | VAF 13/166 reads (8%) | catalogued as rs1557595516; called by muse, mutect2
- MAGEB1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as rs747784071, COSV100975132, COSV66776023; called by muse, mutect2, varscan2
- MAGI2 | c.3686C>T p.T1229M | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746333929, COSV62631835; called by muse, mutect2, varscan2
- MAGI3 | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 34/209 reads (16%) | catalogued as rs764799607; called by muse, mutect2, varscan2
- MAGOHB | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1444451258; called by muse, mutect2, varscan2
- MAJIN | c.194T>C p.F65S | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776305502; called by muse, varscan2
- MALRD1 | c.5374G>A p.V1792I | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs774982488; called by muse, mutect2, varscan2
- MAN2A1 | c.1404del p.F468Lfs*22 | Frame Shift Del (DEL) | VAF 23/173 reads (13%) | catalogued as rs766462976; called by mutect2, pindel, varscan2
- MAN2A2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs766461718; called by muse, varscan2
- MAN2B2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs1396228198; called by muse, mutect2
- MAN2C1 | c.2848G>A p.V950M | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs3803467; called by muse, mutect2
- MAP10 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV69365323; called by muse, mutect2
- MAP1LC3B2 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 68/367 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771512150; called by muse, mutect2, varscan2
- MAP3K3 | c.636C>T p.C212= | Splice Region (SNP) | VAF 30/210 reads (14%) | catalogued as rs1206424482; called by muse, varscan2
- MAP3K4 | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62331785; called by muse, mutect2, varscan2
- MAST4 | c.6152C>T p.A2051V (on ENST00000403625 / NM_001164664.2; = p.A1862V on NM_015183.3) | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs776957434, COSV55134496; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 31/154 reads (20%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MED22 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs587604931, COSV59297296; called by muse, mutect2
- MEGF10 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs986353158; called by muse, mutect2, varscan2
- MEGF8 | c.3406G>A p.V1136M (on ENST00000251268 / NM_001271938.2; = p.V1069M on NM_001410.3) | Missense Mutation (SNP) | VAF 49/336 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs771657070, COSV99235044; called by muse, mutect2, varscan2
- MEGF8 | c.4334G>A p.R1445H (on ENST00000251268 / NM_001271938.2; = p.R1378H on NM_001410.3) | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as rs138904325; called by muse, varscan2
- MEST | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs782807870; called by muse, mutect2
- MEX3A | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1048957799; called by muse, mutect2, varscan2
- MFSD4A | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV65656510; called by mutect2, varscan2
- MGA | c.8567C>T p.P2856L (on ENST00000219905 / NM_001164273.1; = p.P2647L on NM_001080541.2) | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV54961151; called by muse, mutect2, varscan2
- MGMT | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.015); catalogued as rs753401556; called by muse, mutect2, varscan2
- MINK1 | c.3716C>T p.T1239M | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774521244; called by muse, mutect2, varscan2
- MKX | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as rs1482483319; called by muse, mutect2
- MMRN1 | c.3080G>A p.G1027D | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs976747334; called by muse, mutect2
- MPI | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs968235395; called by muse, mutect2, varscan2
- MPP5 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 34/288 reads (12%) | catalogued as rs747419838; called by muse, varscan2
- MPRIP | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs748805990, COSV57928859; called by muse, mutect2, varscan2
- MPV17L | c.457G>A p.A153T (on ENST00000396385 / NM_001128423.2; = p.R129H on NM_173803.4) | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757414085, COSV55009252; called by muse, mutect2, varscan2
- MRPL16 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs768391952; called by muse, mutect2, varscan2
- MST1R | c.2734dup p.D912Gfs*27 | Frame Shift Ins (INS) | VAF 48/306 reads (16%) | catalogued as rs770636237; called by pindel, varscan2
- MTA1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs782149547, COSV100494814; called by muse, mutect2, varscan2
- MTAP | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 25/363 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751881433; called by muse, mutect2
- MTFR1L | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962586; called by muse, mutect2
- MTNR1B | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as rs150751119; called by muse, mutect2, varscan2
- MUC5B | c.5665C>A p.P1889T | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1340307379; called by muse, varscan2
- MUC5B | c.5747C>T p.T1916M | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs772902423, COSV71590678; called by muse, varscan2
- MYBPH | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs558140920; called by muse, mutect2, varscan2
- MYCBPAP | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.409); catalogued as rs376934542; called by muse, mutect2, varscan2
- MYH11 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200447515; called by muse, mutect2, varscan2
- MYH3 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1220315724, COSV56865499; called by muse, mutect2, varscan2
- MYH4 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs185822918; called by muse, mutect2
- MYH9 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs769199813; called by muse, mutect2, varscan2
- MYL10 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV56207637, COSV56207670; called by muse, mutect2, varscan2
- MYO15A | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs763685950, COSV52757036; called by muse, mutect2, varscan2
- MYO15A | c.8812G>A p.G2938R | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780884451, CM165214; called by muse, mutect2, varscan2
- MYO1A | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as rs1015322457, COSV55652326; called by muse, mutect2
- MYO1C | c.2401del p.R801Afs*18 (on ENST00000648651 / NM_001080779.2; = p.R766Afs*18 on NM_033375.5) | Frame Shift Del (DEL) | VAF 35/196 reads (18%) | catalogued as rs1446133378; called by mutect2, pindel, varscan2
- MYO1H | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs190693741; called by muse, mutect2, varscan2
- MYO5A | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs753204590, COSV62560280; called by muse, mutect2, varscan2
- MYO7B | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 84/328 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs964241897; called by muse, mutect2, varscan2
- MYOM1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs746247312; called by muse, mutect2, varscan2
- MYOM3 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs373813223; called by muse, mutect2, varscan2
- MYORG | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99898390; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 51/220 reads (23%) | catalogued as rs763929397; called by mutect2, varscan2
- N4BP2L2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57230177; called by muse, mutect2, varscan2
- NAGPA | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 22/313 reads (7%) | PolyPhen possibly damaging (0.621); catalogued as rs938636342, CM163791; called by muse, mutect2
- NAV3 | c.5677G>T p.E1893* (on ENST00000397909 / NM_001024383.2; = p.E1871* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57110786; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 38/350 reads (11%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, varscan2
- NCSTN | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV54192453; called by muse, mutect2, varscan2
- NDOR1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV61288463; called by muse, mutect2
- NECAB3 | c.102del p.A36Pfs*55 | Frame Shift Del (DEL) | VAF 28/220 reads (13%) | catalogued as rs1568905221; called by mutect2, pindel, varscan2
- NEGR1 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as rs767134486, COSV60828934; called by muse, mutect2
- NELL1 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100119030, COSV54302013; called by muse, mutect2
- NFS1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203932585, COSV100931895; called by muse, mutect2, varscan2
- NID1 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1316537477, COSV51619095; called by muse, varscan2
- NKD1 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 80/468 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs369505855; called by muse, mutect2, varscan2
- NKX2-1 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 28/376 reads (7%) | catalogued as CM080577, COSV61390092; called by muse, mutect2
- NLRP10 | c.1339C>A p.L447M | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100149859, COSV60781607; called by mutect2, varscan2
- NOMO1 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1228317582, COSV55061225; called by muse, mutect2
- NOS1AP | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs1483879517, COSV62639485; called by muse, varscan2
- NOS3 | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104399337; called by muse, varscan2
- NPAS1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs765710648; called by muse, mutect2, varscan2
- NPR1 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1221456184, COSV64141289; called by muse, mutect2
- NPTX1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775122573, COSV60776905; called by muse, mutect2, varscan2
- NPTX2 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200042990; called by muse, mutect2
- NRXN1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.394); catalogued as rs1456330432; called by muse, mutect2
- NRXN2 | c.4521dup p.T1508Hfs*82 | Frame Shift Ins (INS) | VAF 53/380 reads (14%) | catalogued as rs761307555; called by mutect2, varscan2
- NRXN2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV55457959; called by muse, mutect2, varscan2
- NRXN3 | c.1835G>A p.R612H (on ENST00000335750 / NM_001330195.2; = p.R239H on NM_004796.6) | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59744136; called by muse, mutect2
- NT5DC2 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1370217721; called by muse, mutect2
- NUDT10 | c.493T>C p.*165Qext*1 | Nonstop Mutation (SNP) | VAF 6/109 reads (6%) | catalogued as COSV100726829; called by muse, mutect2
- NUFIP1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs776965585; called by muse, mutect2
- NUTM2F | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs549762125; called by muse, varscan2
- NXPE4 | c.1345C>T p.R449* (on ENST00000375478 / NM_001077639.2; = p.R165* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 44/248 reads (18%) | catalogued as rs750280300, COSV100970298, COSV64943495; called by muse, mutect2, varscan2
- NYAP1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 56/457 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs995793426, COSV55719537; called by muse, mutect2, varscan2
- NYAP2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 49/404 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); catalogued as rs376546506; called by muse, mutect2, varscan2
- OBSL1 | c.5045G>A p.R1682H | Missense Mutation (SNP) | VAF 67/433 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1479080818; called by muse, mutect2, varscan2
- OBSL1 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs746057787; called by muse, mutect2
- OPLAH | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1554757955; called by muse, mutect2
- OR10J3 | c.926dup p.N309Kfs*11 | Frame Shift Ins (INS) | VAF 32/219 reads (15%) | catalogued as rs779717612; called by mutect2, pindel, varscan2
- OR13C3 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 110/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374004068, COSV101053227; called by muse, mutect2, varscan2
- OR13C4 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 36/333 reads (11%) | catalogued as rs373326335; called by muse, mutect2, varscan2
- OR2T34 | c.548dup p.C184Lfs*2 | Frame Shift Ins (INS) | VAF 28/210 reads (13%) | catalogued as rs768006394; called by mutect2, varscan2
- OR4K13 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV59859087; called by muse, mutect2, varscan2
- OR51B5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs752700199; called by muse, mutect2, varscan2
- OR52J3 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs577465287, COSV66746663; called by muse, mutect2
- OR5A1 | c.780del p.F260Lfs*12 | Frame Shift Del (DEL) | VAF 39/268 reads (15%) | catalogued as rs773068397; called by mutect2, pindel, varscan2
- OR5AS1 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs372964473; called by muse, mutect2, varscan2
- OR5G3 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as rs969605722; called by muse, mutect2
- OR5J2 | c.51G>T p.L17F | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs770600413, COSV100398927; called by muse, mutect2, varscan2
- OR6C70 | c.304dup p.Y102Lfs*18 | Frame Shift Ins (INS) | VAF 24/208 reads (12%) | catalogued as rs750079585; called by mutect2, varscan2
- OR6C76 | c.699dup p.A234Sfs*66 | Frame Shift Ins (INS) | VAF 24/142 reads (17%) | catalogued as rs771987454; called by mutect2, varscan2
- OR6V1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 36/427 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs200583536, COSV69237609; called by muse, mutect2
- OR7C2 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs747041500; called by mutect2, varscan2
- PAGE5 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.396); catalogued as rs973410659; called by muse, mutect2, varscan2
- PALB2 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1324538307; ClinVar: uncertain significance; called by muse, mutect2
- PANK4 | c.1727+1G>A p.X576_splice | Splice Site (SNP) | VAF 33/216 reads (15%) | catalogued as rs766763222; called by muse, mutect2, varscan2
- PANX2 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.906); catalogued as rs751999520, COSV50302515; called by muse, mutect2, varscan2
- PARD3B | c.2192C>T p.P731L (on ENST00000406610 / NM_001302769.2; = p.P669L on NM_152526.6) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV62536077; called by muse, mutect2, varscan2
- PARD6G | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs149555113; called by muse, varscan2
- PARP6 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs1261119421; called by muse, mutect2, varscan2
- PAX9 | c.311A>C p.D104A | Missense Mutation (SNP) | VAF 71/357 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64062268; called by muse, mutect2, varscan2
- PCDH17 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 56/432 reads (13%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.787); catalogued as rs770772846; called by muse, mutect2, varscan2
- PCDH8 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.053); catalogued as COSV100132082; called by muse, mutect2
- PCDHA10 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as COSV100254468, COSV56507222; called by muse, mutect2
- PCDHA11 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV56501337; called by muse, mutect2
- PCDHA12 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV56510774; called by muse, mutect2, varscan2
- PCDHA9 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); catalogued as rs782653916; called by muse, mutect2, varscan2
- PCDHB3 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554272460, COSV50598514; called by muse, mutect2
- PCDHB4 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 40/566 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV52025300; called by muse, mutect2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2
- PCDHGA4 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.999); catalogued as rs777545006; called by muse, mutect2, varscan2
- PCDHGB6 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV53997307; called by muse, mutect2, varscan2
- PCDHGC3 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.949); catalogued as rs1463314107; called by muse, mutect2, varscan2
- PCDHGC3 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52754014; called by muse, mutect2, varscan2
- PCNT | c.6228del p.K2076Nfs*2 | Frame Shift Del (DEL) | VAF 49/279 reads (18%) | catalogued as COSV64031023; called by mutect2, pindel, varscan2
- PCNT | c.7198C>T p.R2400C | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751297741, COSV64030282; ClinVar: uncertain significance; called by muse, mutect2
- PCNX2 | c.1427del p.G476Efs*66 | Frame Shift Del (DEL) | VAF 33/289 reads (11%) | catalogued as COSV99267762; called by mutect2, pindel, varscan2
- PCYOX1L | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.035); catalogued as rs540565300, COSV51002616; called by muse, mutect2, varscan2
- PDE4A | c.1276T>C p.Y426H (on ENST00000380702 / NM_001111307.2; = p.Y187H on NM_006202.3) | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149107875; called by muse, mutect2, varscan2
- PDLIM5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs760060213; called by mutect2, varscan2
- PDYN | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99452816; called by muse, mutect2
- PDZRN3 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs368761158; called by muse, mutect2, varscan2
- PEAR1 | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV52773910; called by muse, mutect2
- PEMT | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs780565434; called by muse, mutect2, varscan2
- PFKP | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199868194, COSV56539933; called by muse, mutect2, varscan2
- PGAP2 | c.232C>T p.R78C (on ENST00000463452 / NM_001346398.2; = p.R139C on NM_014489.4) | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772273646, COSV53465232; called by muse, mutect2, varscan2
- PGBD1 | c.2275T>C p.Y759H | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV52552283; called by muse, mutect2
- PHACTR3 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 22/215 reads (10%) | catalogued as rs989956811; called by muse, mutect2, varscan2
- PHC1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs1004920975, COSV50004242; called by muse, mutect2, varscan2
- PHRF1 | c.4802A>C p.Q1601P (on ENST00000264555 / NM_001286581.2; = p.Q1600P on NM_020901.4) | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52759972; called by mutect2, varscan2
- PIGT | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV54127671; called by muse, mutect2, varscan2
- PIK3C2G | c.2516del p.N839Mfs*16 (on ENST00000676171; = p.N798Mfs*16 on NM_004570.5) | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | catalogued as rs1229278001; called by mutect2, pindel*, varscan2
- PIK3R1 | c.1072C>T p.R358* (on ENST00000521381 / NM_181523.3; = p.R88* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 33/223 reads (15%) | catalogued as COSV57123913; called by muse, mutect2, varscan2
- PIKFYVE | c.4853T>G p.V1618G | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100011091; called by muse, mutect2, varscan2
- PIPOX | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762419129; called by muse, mutect2, varscan2
- PITPNM3 | c.2904dup p.K969Qfs*108 | Frame Shift Ins (INS) | VAF 37/275 reads (13%) | catalogued as rs777783181; called by mutect2, pindel, varscan2
- PIWIL3 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs757983793, COSV59993796; called by muse, mutect2
- PKD1 | c.6643C>T p.R2215W | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs752793757, CM1313888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKD1L1 | c.5339del p.K1780Rfs*33 | Frame Shift Del (DEL) | VAF 42/265 reads (16%) | catalogued as rs1562955911; called by mutect2, pindel, varscan2
- PKDREJ | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53548671; called by muse, mutect2
- PKMYT1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs1245350543; called by muse, mutect2, varscan2
- PKN3 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1443634612, COSV52578179; called by muse, mutect2
- PLCE1 | c.5410T>C p.F1804L | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as CD084636; called by muse, mutect2
- PLCG1 | c.3322G>A p.V1108M | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1338993174; called by muse, mutect2, varscan2
- PLEC | c.7945_7947del p.E2649del (on ENST00000322810 / NM_201380.4; = p.E2539del on NM_000445.5) | In Frame Del (DEL) | VAF 38/233 reads (16%) | catalogued as rs781849691; called by mutect2, pindel, varscan2
- PLEC | c.536G>A p.R179H (on ENST00000322810 / NM_201380.4; = p.R69H on NM_000445.5) | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs781949709, COSV59606225; called by muse, mutect2
- PLEK | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs754534773, COSV52251303; called by muse, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHF1 | c.244del p.L82Wfs*20 | Frame Shift Del (DEL) | VAF 31/273 reads (11%) | catalogued as COSV101460749; called by mutect2, pindel, varscan2
- PLEKHG2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 33/226 reads (15%) | catalogued as rs747119556, COSV99217433; called by muse, mutect2, varscan2
- PLK1 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100267443; called by muse, mutect2, varscan2
- PLVAP | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as rs766188433; called by muse, varscan2
- PLXNB1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs751688636; called by muse, mutect2, varscan2
- PLXNB3 | c.3931G>T p.D1311Y | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62795400; called by muse, mutect2, varscan2
- PODNL1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 56/352 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs755885466, COSV54309501; called by muse, mutect2, varscan2
- POLL | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as rs370380523; called by muse, mutect2, varscan2
- POLM | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 65/381 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.161); catalogued as rs763360570, COSV104386410; called by muse, mutect2, varscan2
- POLRMT | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 65/421 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752234162; called by muse, mutect2, varscan2
- POMZP3 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV51888120; called by muse, mutect2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 46/383 reads (12%) | catalogued as rs777096925; called by mutect2, pindel, varscan2
- PPP2R1A | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1489963266, COSV59045663; called by muse, mutect2
- PPP6C | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 85/289 reads (29%) | catalogued as COSV65207243; called by muse, mutect2, varscan2
- PRAG1 | c.2279C>T p.T760M | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376983411; called by muse, mutect2, varscan2
- PRAMEF17 | c.1356del p.F452Lfs*44 | Frame Shift Del (DEL) | VAF 35/213 reads (16%) | catalogued as rs1553128626; called by mutect2, pindel, varscan2
- PRDM15 | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54156452; called by muse, mutect2
- PRDX2 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs112697174, COSV56878298; called by muse, mutect2, varscan2
- PRKAR2B | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 85/423 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs1441214566; called by muse, mutect2, varscan2
- PRKDC | c.8326C>T p.R2776W | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370862896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRODH | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.592); catalogued as rs1321845990, COSV104396028; called by muse, mutect2, varscan2
- PRODH2 | c.1344G>A p.M448I (on ENST00000301175; = p.M372I on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as rs1325499874; called by muse, mutect2
- PROX1 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs201989339, COSV99800337; called by muse, mutect2
- PRPF38B | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs779515848, COSV100898205; called by muse, mutect2, varscan2
- PRPF40A | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | catalogued as rs146465592; called by muse, mutect2, varscan2
- PRR22 | c.564dup p.K189Qfs*94 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | catalogued as rs767411497; called by mutect2, pindel
- PRSS22 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs760100029, COSV99362031; called by muse, mutect2, varscan2
- PRUNE2 | c.9037C>T p.R3013* | Nonsense Mutation (SNP) | VAF 62/201 reads (31%) | catalogued as rs775165080; called by muse, mutect2, varscan2
- PSEN1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.675); catalogued as CM951075, COSV56193899; called by muse, mutect2, varscan2
- PSMD3 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319609259, COSV52856489; called by muse, mutect2, varscan2
- PTBP1 | c.995C>T p.A332V (on ENST00000349038 / NM_031991.4; = p.A358V on NM_002819.5) | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs758317861; called by muse, mutect2
- PTGER3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1274753775; called by muse, mutect2, varscan2
- PTPRG | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1559731824, COSV55637474; called by muse, mutect2, varscan2
- PTPRM | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752054284; called by muse, mutect2
- PTPRN | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180421091; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 34/228 reads (15%) | catalogued as COSV100234622; called by mutect2, varscan2
- RACK1 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59319958; called by muse, mutect2, varscan2
- RAI1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs773799612, COSV55399230; called by muse, mutect2
- RAPH1 | c.1370G>A p.R457Q (on ENST00000319170 / NM_213589.3; = p.R509Q on NM_203365.4) | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768545801; called by muse, mutect2, varscan2
- RASGRP3 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1192293060; called by muse, mutect2
- RBFA | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as rs374705895; called by muse, mutect2, varscan2
- RBL1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs753195308; called by muse, mutect2, varscan2
- RBM34 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1418348187; called by muse, mutect2
- RCBTB1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs370652161; called by muse, mutect2
- RDH5 | c.718del p.A240Pfs*7 | Frame Shift Del (DEL) | VAF 24/214 reads (11%) | catalogued as rs753378940, CM991095; called by mutect2, pindel, varscan2
- REEP2 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763379206; called by muse, varscan2
- REEP4 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs138280096, COSV100098286; called by muse, mutect2
- RELN | c.8797A>G p.T2933A | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1172953100; called by muse, mutect2
- REM2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV57465788; called by muse, mutect2
- RFX6 | c.1506del p.F502Lfs*5 | Frame Shift Del (DEL) | VAF 14/160 reads (9%) | catalogued as rs1176756248; called by mutect2, pindel
- RHBDD3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 39/447 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs751207459, COSV53323534; called by muse, mutect2
- RHBDL3 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs1245744325; called by muse, mutect2, varscan2
- RIMS1 | c.3746G>A p.R1249Q | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs199933558; called by muse, mutect2, varscan2
- RIMS2 | c.2050A>T p.I684L (on ENST00000666250 / NM_001348490.2; = p.I492L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV51728077; called by muse, mutect2
- RNF152 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 71/309 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs565129525, COSV57185003; called by muse, mutect2, varscan2
- RNF213 | c.11113G>A p.A3705T | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs545014063; called by muse, mutect2, varscan2
- RNFT2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1165338485; called by muse, mutect2, varscan2
- ROBO2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1405895921, COSV59908258; called by muse, mutect2, varscan2
- ROR1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs369713266; called by muse, varscan2
- RPGRIP1L | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 22/153 reads (14%) | catalogued as rs993394322, COSV50902645; called by muse, mutect2, varscan2
- RRP1B | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs766798880, COSV61479666; called by muse, mutect2
- RUBCN | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769467756; called by muse, mutect2, varscan2
- RUSC2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 115/355 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs758569757, COSV63427619; called by muse, mutect2, varscan2
- RUSC2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777526744; called by muse, mutect2
- RXRA | c.331dup p.L111Pfs*70 | Frame Shift Ins (INS) | VAF 55/322 reads (17%) | catalogued as rs755912201; called by mutect2, varscan2
- RYR1 | c.5891G>A p.R1964H | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767487116, COSV62090903, COSV62109928; called by muse, mutect2, varscan2
- RYR1 | c.7798C>T p.R2600C | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1480598842; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.4751dup p.R1585Afs*29 | Frame Shift Ins (INS) | VAF 25/263 reads (10%) | catalogued as rs766543639; called by mutect2, pindel, varscan2
- S1PR5 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs146786075; called by muse, mutect2, varscan2
- SALL2 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142271078; called by muse, mutect2, varscan2
- SAP130 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs561114474, COSV52099519; called by muse, mutect2, varscan2
- SARDH | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.216); catalogued as rs537958131; called by muse, mutect2, varscan2
- SCAF1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1212804770; called by muse, mutect2, varscan2
- SCARA3 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs573630866, COSV57271585; called by muse, mutect2, varscan2
- SCARA5 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765044292, COSV57277440; called by muse, mutect2
- SCN1A | c.5342A>G p.Y1781C (on ENST00000303395 / NM_001202435.3; = p.Y1770C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918779, CM044052; ClinVar: not provided; called by muse, mutect2, varscan2
- SCN4A | c.2919del p.E974Rfs*67 | Frame Shift Del (DEL) | VAF 30/296 reads (10%) | catalogued as rs1567819905; called by mutect2, pindel, varscan2
- SDK2 | c.1447del p.V483Sfs*8 | Frame Shift Del (DEL) | VAF 47/259 reads (18%) | catalogued as COSV66183488; called by mutect2, pindel, varscan2
- SEC63 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs776025014; called by muse, mutect2, varscan2
- SELENOI | c.1139T>C p.L380S | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs769462279; called by muse, mutect2
- SEMA3G | c.500G>C p.R167P | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs550066410, COSV99039919, COSV99203678; called by mutect2, varscan2
- SEMA4A | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV61772527; called by muse, mutect2, varscan2
- SEMA6C | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs1423768913, COSV59003796; called by muse, mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SERPINA10 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754802803, COSV56228180; called by muse, mutect2, varscan2
- SERPINA4 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.494); catalogued as rs766561113; called by muse, mutect2, varscan2
- SETD1A | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs745869079; called by muse, mutect2, varscan2
- SGK1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.106); catalogued as rs750204554, COSV52806023; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SH2B2 | c.1877del p.P626Rfs*65 | Frame Shift Del (DEL) | VAF 39/245 reads (16%) | catalogued as rs1364524355; called by mutect2, pindel, varscan2
- SH2D5 | c.599G>A p.R200Q (on ENST00000444387 / NM_001103161.2; = p.R116Q on NM_001103160.2) | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376043691; called by muse, mutect2, varscan2
- SH2D7 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs974373426; called by muse, mutect2, varscan2
- SH3TC2 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs144655516; ClinVar: uncertain significance; called by muse, varscan2
- SHANK2 | c.4095del p.E1366Sfs*20 | Frame Shift Del (DEL) | VAF 43/225 reads (19%) | catalogued as COSV53620910; called by mutect2, pindel, varscan2
- SHANK2 | c.207G>A p.T69= | Splice Region (SNP) | VAF 18/194 reads (9%) | catalogued as rs1269420461; called by muse, mutect2
- SHARPIN | c.1004del p.P335Qfs*77 | Frame Shift Del (DEL) | VAF 40/258 reads (16%) | catalogued as COSV59644548; called by mutect2, varscan2
- SHMT1 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs763679038, COSV100363518; called by muse, mutect2, varscan2
- SIAE | c.1229A>C p.E410A | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV99422545; called by muse, mutect2
- SIDT1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs751830248; called by muse, mutect2, varscan2
- SIGLEC11 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as rs761326314; called by muse, mutect2, varscan2
- SKIV2L | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 30/351 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.761); catalogued as rs774644201, COSV61713745; called by muse, mutect2
- SLAIN2 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 23/331 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99077827; called by muse, mutect2
- SLC12A6 | c.3223C>T p.R1075C (on ENST00000354181 / NM_001365088.1; = p.R1024C on NM_005135.2) | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV99270790; called by muse, mutect2, varscan2
- SLC15A3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs370679611, COSV57171862; called by muse, mutect2, varscan2
- SLC16A2 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780086745; ClinVar: uncertain significance; called by muse, varscan2
- SLC20A2 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 72/356 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as rs746847751; called by muse, mutect2, varscan2
- SLC22A2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs751773139, COSV65265576; called by muse, mutect2, varscan2
- SLC25A1 | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 14/224 reads (6%) | catalogued as rs781974501; called by muse, mutect2
- SLC25A32 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs762142083; called by muse, mutect2, varscan2
- SLC26A3 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 26/395 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV60642469; called by muse, mutect2
- SLC27A1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs1004163457, COSV53096150; called by muse, mutect2
- SLC35C2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs374923887, COSV54756040; called by muse, mutect2, varscan2
- SLC38A3 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 50/275 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1331818148; called by muse, mutect2, varscan2
- SLC47A1 | c.1324A>T p.I442F | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1222644782; called by muse, mutect2, varscan2
- SLITRK3 | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs771111395; called by muse, mutect2, varscan2
- SLITRK5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100281408; called by muse, mutect2
- SMARCAD1 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1440635478, COSV100759022; called by muse, mutect2
- SMCHD1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1356682578; called by muse, mutect2, varscan2
- SMIM6 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332160375; called by muse, mutect2
- SMPD3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs775387559, COSV54710984; called by muse, mutect2, varscan2
- SNAPC4 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 83/443 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs372184757; called by muse, mutect2, varscan2
- SNCG | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs184050583; called by muse, mutect2, varscan2
- SNN | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs8191328; called by muse, mutect2, varscan2
- SNX27 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs752336635, COSV64327905; called by muse, mutect2, varscan2
- SOAT1 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772270018; called by muse, mutect2, varscan2
- SOCS7 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1555568626; called by muse, varscan2
- SOCS7 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs764813391; called by muse, varscan2
- SON | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs200562824; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel
- SOX1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.874); catalogued as rs1398178334; called by muse, mutect2
- SPAG17 | c.3263G>A p.G1088E | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749074745; called by muse, mutect2
- SPAG17 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs772685293, COSV60453868; called by muse, mutect2, varscan2
- SPEN | c.6650C>T p.A2217V | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779675366, COSV65366472; called by muse, mutect2, varscan2
- SPHKAP | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs753808266, COSV60878434; called by muse, mutect2
- SPIN1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs982498128; called by muse, mutect2
- SPINT3 | c.45_46del p.C16Pfs*41 | Frame Shift Del (DEL) | VAF 32/200 reads (16%) | catalogued as rs1251695045; called by pindel, varscan2
- SPN | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201256378, COSV64071238; called by muse, mutect2, varscan2
- SPO11 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.254); catalogued as rs1197557203; called by muse, mutect2
- SPOPL | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1445542070; called by muse, varscan2
- SPTBN1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs921219631, COSV100777351, COSV63346833; called by muse, mutect2, varscan2
- SPTBN2 | c.5529_5530del p.A1844Lfs*4 | Frame Shift Del (DEL) | VAF 35/229 reads (15%) | catalogued as rs775808781; called by pindel, varscan2
- SPTBN4 | c.5008G>A p.V1670M | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1375909686; called by muse, mutect2
- SPTBN5 | c.10118T>C p.L3373P | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1367481383; called by muse, mutect2, varscan2
- SRCAP | c.399del p.G135Vfs*35 | Frame Shift Del (DEL) | VAF 43/272 reads (16%) | catalogued as COSV52670213; called by mutect2, pindel, varscan2
- SRRM2 | c.5048G>A p.R1683H | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs749796177; called by mutect2, varscan2
- SSBP4 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs192982931; called by muse, mutect2, varscan2
- STARD3 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748976068; called by muse, mutect2, varscan2
- STX11 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62448561; called by muse, mutect2, varscan2
- SUCLG1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs1271138534; called by muse, mutect2
- SUPT5H | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.264); catalogued as rs761391829; called by muse, mutect2, varscan2
- SVIL | c.4481C>T p.A1494V (on ENST00000355867 / NM_021738.3; = p.A1068V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs753738627, COSV63445056; called by muse, mutect2
- SVIL | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs138346979; called by muse, mutect2, varscan2
- SVOPL | c.976dup p.D326Gfs*18 (on ENST00000419765; = p.D174Gfs*18 on NM_174959.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 66/308 reads (21%) | catalogued as rs769304357; called by mutect2, varscan2
- SWT1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781405989, COSV62255008; called by muse, mutect2, varscan2
- SYN1 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs1249900243; called by muse, mutect2
- SYNE1 | c.1021G>A p.E341K (on ENST00000367255 / NM_182961.4; = p.E348K on NM_033071.3) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs1203553546, COSV99554458; called by muse, mutect2, varscan2
- SYNM | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs782022980; called by muse, mutect2, varscan2
- TACR3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59202383; called by muse, mutect2
1,822 further variants in this file (1,125 protein-altering or splice-affecting, 622 silent, 75 other) are not listed here.
